Somatic mutation profile of tumor specimen 0DWM1M from CCDI case PBCPHN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 20.6 years (7,511 days).
Specimen 0DWM1M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5aa8802-810e-4c5f-acc0-c6fcc55b176f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWLYT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49b01536-6df6-4201-9e96-db6387a5e382

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 3'UTR 3, 5'UTR 2, Intron 2, Silent 1, 5'Flank 1, Frame Shift Del 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 99/311 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 234/290 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.3100C>T p.Q1034* | Nonsense Mutation (SNP) | VAF 176/214 reads (82%) | catalogued as COSV64870622; called by muse, mutect2, varscan2
- CELSR3 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 188/439 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50850078; called by muse, mutect2, varscan2
- HELZ2 | c.6727C>T p.R2243C (on ENST00000467148 / NM_001037335.2; = p.R1674C on NM_033405.3) | Missense Mutation (SNP) | VAF 44/836 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756636547; called by muse, mutect2
- STAG2 | c.1393G>T p.V465F | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV54356033; called by muse, mutect2
- TPR | c.6976G>T p.V2326L | Missense Mutation (SNP) | VAF 12/390 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.043); catalogued as COSV104422649, COSV63355178; called by muse, mutect2
- CD163L1 | c.2828G>C p.C943S | Missense Mutation (SNP) | VAF 11/341 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LACTB | c.1148_1152del p.L383Qfs*7 | Frame Shift Del (DEL) | VAF 55/252 reads (22%) | called by mutect2, pindel, varscan2
- TCF25 | c.1470-8T>C | Splice Region (SNP) | VAF 17/426 reads (4%) | called by muse, mutect2
- TRPC3 | c.1033G>A p.G345S (on ENST00000379645 / NM_001366479.2; = p.G272S on NM_003305.2) | Missense Mutation (SNP) | VAF 136/398 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- WNT4 | c.89A>C p.K30T | Missense Mutation (SNP) | VAF 116/435 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- COBL | c.1443A>G p.E481= | Silent (SNP) | VAF 179/470 reads (38%) | catalogued as COSV54338534; called by mutect2, varscan2
- ABCC9 | chr12:21936683 A>C | 5'Flank (SNP) | VAF 68/255 reads (27%) | called by muse, mutect2, varscan2
- ALPL | c.*20C>A | 3'UTR (SNP) | VAF 111/319 reads (35%) | called by muse, mutect2, varscan2
- B3GNT6 | c.*92C>A | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- CCT4 | c.-9G>C | 5'UTR (SNP) | VAF 79/171 reads (46%) | called by muse, mutect2, varscan2
- MLIP | c.613-11288G>A | Intron (SNP) | VAF 99/419 reads (24%) | called by muse, mutect2, varscan2
- NFATC4 | c.-54T>C | 5'UTR (SNP) | VAF 62/155 reads (40%) | called by muse, mutect2, varscan2
- PRMT7 | c.1056-24C>G | Intron (SNP) | VAF 50/138 reads (36%) | called by mutect2, varscan2
- UBAP2L | c.*27_*31del | 3'UTR (DEL) | VAF 49/192 reads (26%) | called by mutect2, pindel, varscan2
